Somatic mutation profile of tumor specimen MP2PRT-PASZEJ-TMP1-A (aliquot MP2PRT-PASZEJ-TMP1-A-2-0-D-A79Q-36) from MP2PRT case MP2PRT-PASZEJ, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 2.6 years (964 days).
Specimen MP2PRT-PASZEJ-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 5cc69991-0911-4b31-b200-cd4475fb91ab.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PASZEJ-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PASZEJ-NB1-A-1-0-D-A79Q-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/7e1da8b7-6f70-41c2-b449-e647ee780b98

The open-access MAF lists 28 somatic variants for this specimen: 22 protein-altering or splice-affecting, 5 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 19, Silent 5, Frame Shift Ins 2, Frame Shift Del 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PTPN11 | c.226G>A p.E76K | Missense Mutation (SNP) | VAF 103/322 reads (32%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen probably damaging (0.947); catalogued as rs121918464, COSV61004751, COSV61004889; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- CEACAM21 | c.850G>A p.G284S (on ENST00000401445 / NM_001098506.4; = p.G283S on NM_033543.6) | Missense Mutation (SNP) | VAF 92/355 reads (26%) | SIFT tolerated (0.63); PolyPhen benign (0.013); catalogued as rs199631079, COSV99079010; called by muse, mutect2, varscan2
- CEP112 | c.110G>A p.R37Q | Missense Mutation (SNP) | VAF 91/350 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as rs1287529976; called by muse, mutect2, varscan2
- DAAM2 | c.2960G>A p.R987Q (on ENST00000274867 / NM_001201427.2; = p.R986Q on NM_015345.3) | Missense Mutation (SNP) | VAF 65/400 reads (16%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.695); catalogued as rs375987274; called by muse, mutect2, varscan2
- DNAH7 | c.6616C>T p.R2206C | Missense Mutation (SNP) | VAF 39/141 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs766863216, COSV56786144; called by muse, mutect2, varscan2
- KRT13 | c.1070C>T p.A357V | Missense Mutation (SNP) | VAF 105/459 reads (23%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.867); catalogued as rs745938353; called by muse, mutect2, varscan2
- LCOR | c.232G>A p.E78K | Missense Mutation (SNP) | VAF 39/227 reads (17%) | SIFT deleterious (0.05); PolyPhen benign (0.086); catalogued as rs746469489, COSV100603622; called by muse, mutect2, varscan2
- MUC17 | c.3686C>T p.T1229M | Missense Mutation (SNP) | VAF 78/360 reads (22%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as rs771303338, COSV60281126; called by muse, mutect2, varscan2
- OR5C1 | c.506G>A p.R169H | Missense Mutation (SNP) | VAF 83/366 reads (23%) | SIFT tolerated (0.1); PolyPhen benign (0.029); catalogued as rs757072623, COSV65456075; called by muse, mutect2, varscan2
- OTOP1 | c.859G>A p.V287I | Missense Mutation (SNP) | VAF 74/380 reads (19%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.524); catalogued as rs143243019; called by muse, mutect2, varscan2
- PHYHIPL | c.766G>A p.A256T | Missense Mutation (SNP) | VAF 103/448 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs369674396, COSV99514224; called by muse, mutect2, varscan2
- VEGFC | c.559G>A p.E187K | Missense Mutation (SNP) | VAF 52/242 reads (21%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV54595855; called by muse, varscan2
- WDR3 | c.572G>A p.R191Q | Missense Mutation (SNP) | VAF 49/167 reads (29%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs774316410, COSV62522871; called by muse, mutect2, varscan2
- DPY19L3 | c.764G>C p.S255T | Missense Mutation (SNP) | VAF 65/229 reads (28%) | SIFT tolerated (0.47); PolyPhen possibly damaging (0.446); called by muse, mutect2, varscan2
- FCGR2A | c.30_31insC p.V11Rfs*36 (on ENST00000271450 / NM_001136219.3; = p.V11Rfs*35 on NM_021642.5 and 1 other RefSeq transcript) | Frame Shift Ins (INS) | VAF 74/361 reads (20%) | called by mutect2, pindel*, varscan2
- MYEF2 | c.241C>T p.H81Y | Missense Mutation (SNP) | VAF 59/259 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); called by muse, mutect2, varscan2
- NDST3 | c.38G>A p.R13K | Missense Mutation (SNP) | VAF 109/247 reads (44%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.211); called by muse, mutect2, varscan2
- PPP4R3C | c.151A>T p.I51F | Missense Mutation (SNP) | VAF 25/301 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.826); called by muse, mutect2
- PTBP2 | c.1561C>T p.H521Y (on ENST00000426398 / NM_001300986.2; = p.H512Y on NM_021190.4) | Missense Mutation (SNP) | VAF 70/263 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- TCHH | c.3144_3148delinsCTGGGGA p.R1048Sfs*48 | Frame Shift Ins (INS) | VAF 73/565 reads (13%) | called by pindel, varscan2*
- TNFAIP1 | c.868G>T p.D290Y | Missense Mutation (SNP) | VAF 103/471 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.284); called by muse, mutect2, varscan2
- YEATS2 | c.1853_1854del p.V618Efs*128 | Frame Shift Del (DEL) | VAF 90/378 reads (24%) | called by pindel, varscan2
- FAT1 | c.543C>T p.N181= | Silent (SNP) | VAF 111/477 reads (23%) | catalogued as rs777213391, COSV71674335; called by muse, mutect2, varscan2
- IGKV1OR2-108 | c.352_353del p.*118del | Silent (DEL) | VAF 61/197 reads (31%) | called by mutect2, pindel*, varscan2*
- IHH | c.513G>A p.V171= | Silent (SNP) | VAF 122/436 reads (28%) | called by muse, mutect2, varscan2
- PIWIL1 | c.1704C>T p.Y568= | Silent (SNP) | VAF 88/327 reads (27%) | catalogued as rs151261790; called by muse, mutect2, varscan2
- UPK3B | c.108C>T p.D36= | Silent (SNP) | VAF 174/796 reads (22%) | catalogued as rs551730871; called by muse, mutect2, varscan2
- TNRC18 | c.487+120_487+126del | Intron (DEL) | VAF 52/185 reads (28%) | called by mutect2, pindel*
